Somatic mutation profile of tumor specimen TCGA-EY-A1GX-01A (aliquot TCGA-EY-A1GX-01A-12D-A13L-09) from TCGA case TCGA-EY-A1GX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 76.6 years (27,962 days).
Specimen TCGA-EY-A1GX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 525fd284-582f-45e3-ae97-72726b38ad6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GX-10A (Blood Derived Normal), aliquot TCGA-EY-A1GX-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2f28c6b-f709-4efe-a33a-864ab154c499

The open-access MAF lists 86 somatic variants for this specimen: 63 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 22, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 16/17 reads (94%) | hotspot (GDC flag); catalogued as rs587782607, CM116000, COSV100909697, COSV64292178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- AC004593.2 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs142788210, COSV56096753; called by muse, mutect2, varscan2
- ANKRD24 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99517338; called by muse, mutect2, varscan2
- BAZ1A | c.4646C>T p.P1549L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs541683224, COSV62411134; called by muse, mutect2, varscan2
- BOC | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.362); catalogued as rs751976756, COSV56349674; called by muse, mutect2, varscan2
- C5 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV56327312, COSV56331929; called by muse, mutect2, varscan2
- CD163L1 | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.039); catalogued as rs200548297, COSV100549961; called by muse, mutect2, varscan2
- CNTNAP5 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs769500372, COSV101443367, COSV70472741; called by muse, mutect2, varscan2
- COL24A1 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993162; called by muse, mutect2, varscan2
- CYP4Z1 | c.1418T>A p.F473Y | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100497616; called by muse, mutect2, varscan2
- DLG5 | c.4723C>T p.R1575C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1382546442, COSV64947365; called by muse, mutect2, varscan2
- DNAH9 | c.10453C>T p.R3485W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs370956573; called by muse, varscan2
- EPAS1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs759634197, CM148529, COSV55384867; called by muse, mutect2, varscan2
- EPHA3 | c.893A>C p.E298A | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0.089); catalogued as COSV100344465; called by muse, mutect2, varscan2
- FAM110C | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as COSV100566844, COSV100566918; called by muse, mutect2, varscan2
- FLNC | c.7761_7762insA p.F2588Ifs*93 | Frame Shift Ins (INS) | VAF 91/161 reads (57%) | catalogued as COSV100367935; called by mutect2, pindel, varscan2
- FMC1-LUC7L2 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99880551; called by muse, mutect2, varscan2
- FRG2B | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101423512; called by muse, mutect2, varscan2
- GDPD5 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs748495456, COSV100409257; called by muse, mutect2, varscan2
- GIGYF2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs755964159, COSV65251603; called by muse, mutect2, varscan2
- GLUD2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV100046724; called by muse, mutect2, varscan2
- GPR141 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100550289; called by muse, mutect2, varscan2
- KIF19 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370601800; called by muse, mutect2, varscan2
- KLHL28 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100753073, COSV61889705; called by muse, mutect2, varscan2
- KMT2E | c.2275C>A p.R759S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57575555, COSV99996133; called by muse, mutect2, varscan2
- L1CAM | c.1984T>C p.W662R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649035; called by muse, mutect2, varscan2
- LRRIQ1 | c.2544G>T p.Q848H | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1211708680, COSV101280017; called by muse, mutect2, varscan2
- LSAMP | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as rs956639634, COSV100370050; called by muse, mutect2, varscan2
- LTN1 | c.5113G>A p.V1705I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as rs190799686, COSV100797946; called by muse, mutect2, varscan2
- MANSC1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs774607079, COSV101115808; called by muse, mutect2, varscan2
- MGA | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 31/54 reads (57%) | catalogued as COSV99579480; called by muse, mutect2, varscan2
- MLST8 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755425949, COSV100063401; called by muse, mutect2, varscan2
- MYO5C | c.2515G>T p.A839S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV99954568; called by muse, mutect2, varscan2
- NEXMIF | c.3223G>T p.D1075Y | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99280443; called by muse, mutect2, varscan2
- NFKBIL1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as rs777929159, COSV58214708; called by muse, mutect2, varscan2
- NLRP1 | c.3431G>T p.S1144I | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99333701; called by muse, mutect2, varscan2
- NME8 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV99553139; called by muse, mutect2, varscan2
- NSD3 | c.3961G>T p.E1321* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV57672247; called by muse, mutect2, varscan2
- NUB1 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879262; called by muse, mutect2, varscan2
- OBSCN | c.16739G>A p.R5580Q | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763888752, COSV99476432; called by muse, mutect2, varscan2
- OR10H2 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1429490634, COSV100008722; called by muse, mutect2, varscan2
- PMEL | c.1798G>A p.V600M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs746474705, COSV59386459; called by muse, mutect2, varscan2
- PODXL | c.1352C>T p.P451L (on ENST00000378555 / NM_001018111.3; = p.P419L on NM_005397.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs145330930; called by muse, mutect2, varscan2
- POU3F1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100884679; called by muse, mutect2, varscan2
- PSPC1 | c.1424T>C p.M475T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV100142258; called by muse, mutect2, varscan2
- PTPRN | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99833894; called by muse, mutect2, varscan2
- RASAL1 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs756109348, COSV99921625; called by muse, mutect2, varscan2
- RIF1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs776895432, COSV99690431; called by muse, mutect2, varscan2
- RTP1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56618662; called by muse, mutect2, varscan2
- RUSC2 | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs141116165; called by muse, mutect2, varscan2
- SF3A2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV99677730; called by muse, mutect2, varscan2
- SIRPA | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV100605143; called by muse, mutect2, varscan2
- SZT2 | c.2072T>A p.L691Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100987125; called by muse, mutect2, varscan2
- TMEM208 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.093); catalogued as COSV50768530; called by muse, mutect2, varscan2
- TSN | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441568864, COSV101067476; called by muse, mutect2, varscan2
- VPS13A | c.8099G>A p.R2700H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV62426426; called by muse, mutect2, varscan2
- ZBTB40 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100988904; called by muse, mutect2, varscan2
- ZNF507 | c.2477C>G p.A826G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321770, COSV61332958; called by muse, mutect2, varscan2
- CREBBP | c.5280_5283del p.S1761Rfs*9 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- FRG2C | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM7 | c.1923_1930del p.I642Pfs*41 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- OR9G1 | c.814dup p.I272Nfs*23 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- ATP10D | c.453G>A p.Q151= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99905488; called by muse, mutect2
- CBX5 | c.87C>T p.R29= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs747285924, COSV99267556; called by muse, mutect2, varscan2
- CEP95 | c.813G>A p.E271= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1555678233, COSV101616312, COSV73608869; called by muse, mutect2, varscan2
- COL6A1 | c.2733C>T p.N911= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as rs144585693; ClinVar: uncertain significance; called by muse, mutect2
- FAN1 | c.2328T>C p.D776= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100755924; called by muse, mutect2, varscan2
- IGLC2 | c.321G>A p.*107= | Silent (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.561C>T p.C187= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs559918202, COSV100583846; called by muse, mutect2, varscan2
- KCNH6 | c.2301G>A p.Q767= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100120946; called by muse, mutect2, varscan2
- MAP1A | c.48C>T p.D16= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs767470927, COSV55807181; called by muse, mutect2, varscan2
- MUC5B | c.9393G>A p.T3131= | Silent (SNP) | VAF 65/66 reads (98%) | catalogued as rs778855110, COSV71589943; called by muse, mutect2, varscan2
- MYH13 | c.5730C>T p.A1910= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs745705315, COSV99353465; called by muse, varscan2
- MYH13 | c.2751C>A p.I917= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV99353469; called by muse, mutect2, varscan2
- NUP210 | c.378C>T p.R126= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs745492911, COSV99596008; called by muse, mutect2, varscan2
- OR4C13 | c.921T>C p.S307= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as rs557163061, COSV101634163; called by muse, mutect2
- PLXNB1 | c.5139G>T p.G1713= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV56488823, COSV99602681; called by muse, mutect2, varscan2
- ROBO3 | c.2130C>T p.G710= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV101185013; called by muse, mutect2, varscan2
- SLC30A4 | c.1192T>C p.L398= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs769954421, COSV99970209; called by muse, mutect2, varscan2
- TENM4 | c.6795C>T p.G2265= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as rs577179110, COSV53643016; called by muse, mutect2, varscan2
- TP53BP1 | c.4842A>T p.A1614= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99780294; called by muse, mutect2, varscan2
- TRPC4 | c.2043G>A p.K681= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV59015024; called by muse, mutect2
- WSB2 | c.384G>A p.T128= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs779713610, COSV59574129; called by muse, mutect2, varscan2
- ZFYVE9 | c.2259C>T p.C753= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99819795; called by muse, mutect2, varscan2
- WT1 | chr11:32439145 G>A | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
